Gene-level copy-number profile of tumor specimen TCGA-MP-A4T9-01A from TCGA case TCGA-MP-A4T9, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.1 years (19,767 days).
Specimen TCGA-MP-A4T9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.abe8354d-ec28-45ba-98fa-0afac732ea67.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,709 have no estimate.
https://portal.gdc.cancer.gov/files/79ecbd95-333c-4933-957a-625a8826e2d6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 13,800; copy number 2: 28,104; copy number 3: 13,838; copy number 4: 605; copy number 5: 403; copy number 7: 162.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MP-A4T9-01A-11D-A24O-01): tumor purity 0.18, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:285,443–351,355, 2 genes: AL365272.1, DUSP22.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 565 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:175,315,194–175,743,616, 2 genes, copy number 7 (within-gene range 3–7): TNR, TNR-IT1.
- chr5:10,971,836–11,904,446, 1 gene, copy number 7 (within-gene range 4–7): CTNND2.
- chr7:70,972–6,859,830, 168 genes, copy number 5 (broad region; genes not listed).
- chr7:38,341,577–38,378,804, 1 gene, copy number 5 (within-gene range 4–5): TRG-AS1.
- chr7:38,362,864–62,275,678, 390 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr12:31,111,652–31,201,235, 1 gene, copy number 7: AC024940.1.
- chr17:36,116,177–36,177,510, 1 gene, copy number 7: AC243829.2.
- chr22:15,746,630–15,778,297, 1 gene, copy number 7: PSLNR.

Autosomal genes at a single copy (total copy number 1): 13,800. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
